Somatic mutation profile of tumor specimen TCGA-N7-A4Y8-01A (aliquot TCGA-N7-A4Y8-01A-11D-A28R-08) from TCGA case TCGA-N7-A4Y8, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IVB; Age at diagnosis: 73.0 years (26,650 days).
Specimen TCGA-N7-A4Y8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6ce63ed-20bf-46e6-82c0-cc2cbf500d70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N7-A4Y8-10A (Blood Derived Normal), aliquot TCGA-N7-A4Y8-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c19476e-09f5-4363-8c5f-efccc952cc17

The open-access MAF lists 54 somatic variants for this specimen: 42 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 10, Splice Site 2, RNA 2, In Frame Del 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 79/288 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519891, COSV57247504, COSV57260861, COSV57263527; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 34/106 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 9/87 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.716A>G p.N239S | Missense Mutation (SNP) | VAF 62/67 reads (93%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as rs1057519999, COSV52661127, COSV52664176, COSV52966384; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.2912G>A p.R971Q (on ENST00000506720 / NM_001322402.2; = p.R903Q on NM_015236.6) | Missense Mutation (SNP) | VAF 74/151 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs771097660, COSV72230590, COSV72231107; called by muse, mutect2, varscan2
- BSN | c.7648C>T p.R2550C | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs150764510; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4823G>A p.S1608N | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs199902405; called by muse, mutect2, varscan2
- CFAP36 | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.946); catalogued as rs748634021; called by muse, mutect2, varscan2
- CHRM3 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1221241600; called by muse, mutect2, varscan2
- CRLF1 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs926518620; called by muse, mutect2, varscan2
- DVL1 | c.1391G>A p.R464Q (on ENST00000378888 / NM_001330311.2; = p.R439Q on NM_004421.3) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1232376736; called by muse, mutect2, varscan2
- ELN | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs375116795; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- NRDC | c.2207C>T p.T736M | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs749568025, COSV61405214; called by muse, mutect2, varscan2
- PCDHA12 | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.16); catalogued as rs1554169943, COSV56518267; called by muse, mutect2, varscan2
- PROSER1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769482816, COSV61488375; called by muse, mutect2, varscan2
- PRRX2 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.101); catalogued as rs994213997, COSV100991162; called by muse, mutect2, varscan2
- SLC15A1 | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs532061967, COSV64732544; called by muse, mutect2, varscan2
- SRM | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs751464593; called by muse, mutect2, varscan2
- TRPC1 | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as rs759921709; called by muse, varscan2
- ACTA1 | c.129+1G>T p.X43_splice | Splice Site (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- BMS1 | c.3010-2A>G p.X1004_splice | Splice Site (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2
- COL15A1 | c.422C>G p.P141R | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ERGIC2 | c.1121A>G p.N374S | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by muse, mutect2
- GEMIN5 | c.1528C>T p.H510Y | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HLA-E | c.175A>G p.N59D | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- IL1R2 | c.493G>C p.V165L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ITGA1 | c.1094C>T p.T365I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ITPKA | c.1060C>G p.Q354E | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- NRG1 | c.1047G>T p.Q349H (on ENST00000405005 / NM_013964.5; = p.Q354H on NM_013956.5) | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- NUP153 | c.2233T>G p.C745G | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4C12 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR5K1 | c.620_621del p.Q207Rfs*6 | Frame Shift Del (DEL) | VAF 40/120 reads (33%) | called by mutect2, pindel, varscan2
- PDIA4 | c.1520A>G p.K507R (on ENST00000286091 / NM_001371244.1; = p.K506R on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/236 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLXNB2 | c.3806_3814del p.E1269_I1272delinsV | In Frame Del (DEL) | VAF 29/36 reads (81%) | called by mutect2, pindel, varscan2
- PTPRF | c.1592C>A p.S531* | Nonsense Mutation (SNP) | VAF 39/77 reads (51%) | called by muse, mutect2, varscan2
- SLC44A1 | c.571_579del p.L191_T193del | In Frame Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- SRRM1 | c.2663G>A p.R888H | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- STING1 | c.379T>A p.S127T | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- TH | c.1400G>A p.S467N (on ENST00000381178 / NM_199292.3; = p.S436N on NM_000360.4) | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.085); called by muse, mutect2
- YPEL4 | c.268T>C p.C90R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF251 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- AK9 | c.5466A>G p.L1822= | Silent (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- FAM161B | c.1488C>T p.P496= (on ENST00000651776; = p.P433= on NM_152445.3) | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs759037058; called by muse, mutect2, varscan2
- IFFO1 | c.219C>T p.N73= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs1192967778, COSV59112184; called by muse, mutect2, varscan2
- LRRN2 | c.144C>T p.R48= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as rs781709899, COSV100912870, COSV65784154; called by muse, mutect2, varscan2
- NOMO1 | c.3294C>T p.F1098= | Silent (SNP) | VAF 39/114 reads (34%) | called by muse, mutect2, varscan2
- NPY2R | c.342G>A p.G114= | Silent (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- RBM28 | c.1635G>A p.A545= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs1420008201, COSV56165322; called by muse, mutect2, varscan2
- SCYL1 | c.1311C>T p.A437= | Silent (SNP) | VAF 61/329 reads (19%) | called by muse, mutect2, varscan2
- SLC7A13 | c.978A>C p.L326= | Silent (SNP) | VAF 7/162 reads (4%) | called by muse, mutect2
- SYBU | c.858G>A p.K286= (on ENST00000276646 / NM_001099754.2; = p.K285= on NM_017786.6) | Silent (SNP) | VAF 50/177 reads (28%) | called by muse, mutect2, varscan2
- FXYD6P3 | n.36C>T | RNA (SNP) | VAF 45/53 reads (85%) | called by muse, mutect2, varscan2
- SSPOP | n.7564C>T | RNA (SNP) | VAF 10/32 reads (31%) | catalogued as rs376922559; called by muse, mutect2, varscan2
